Somatic mutation profile of tumor specimen ALCH-B2PY-TTP1-A (aliquot ALCH-B2PY-TTP1-A-1-0-D-A77Z-36) from ALCHEMIST case ALCH-B2PY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.6 years (22,118 days).
Specimen ALCH-B2PY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 781a4182-6fca-424e-a4aa-5c4c474154d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2PY-NB1-A (Blood Derived Normal), aliquot ALCH-B2PY-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bd80df5-097e-4f62-ac3b-9575a615f00e

The open-access MAF lists 39 somatic variants for this specimen: 22 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 14, Intron 3, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASIC1 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.086); catalogued as rs373616682; called by muse, mutect2, varscan2
- CPA1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs1186893434; called by muse, mutect2, varscan2
- CRYBB3 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 42/347 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs374984300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRC1 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 66/1403 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.989); catalogued as rs531857366; called by muse, mutect2
- MTUS2 | c.2719G>A p.G907S | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771360886, COSV54993678; called by muse, mutect2, varscan2
- NCAPD2 | c.3170G>A p.R1057H | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs780783630; called by muse, mutect2, varscan2
- NEU4 | c.394G>A p.A132T (on ENST00000391969 / NM_001167602.3; = p.A144T on NM_080741.4) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs766104247; called by muse, mutect2, varscan2
- VPS35 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 18/703 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1367504626; called by muse, mutect2
- COL5A3 | c.4436C>A p.P1479H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.888); called by mutect2, varscan2
- DNAH12 | c.5430C>A p.N1810K (on ENST00000351747; = p.N1829K on NM_001366028.2) | Missense Mutation (SNP) | VAF 50/928 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.01); called by muse, mutect2
- DNAH9 | c.3479G>A p.S1160N | Missense Mutation (SNP) | VAF 64/870 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- ETV2 | c.461G>A p.W154* | Nonsense Mutation (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- FASN | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FCRL2 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FDXR | c.618C>A p.D206E (on ENST00000293195 / NM_024417.5; = p.D212E on NM_004110.6) | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IRF7 | c.497G>A p.G166E (on ENST00000397566; = p.G153E on NM_001572.5) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP1R10 | c.1229A>T p.Y410F | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RASA1 | c.539+5G>C | Splice Region (SNP) | VAF 48/920 reads (5%) | called by muse, mutect2
- RDH11 | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 54/402 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- THOC1 | c.1570A>T p.N524Y | Missense Mutation (SNP) | VAF 15/347 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2
- TLR4 | c.846T>A p.N282K (on ENST00000355622 / NM_138554.5; = p.N242K on NM_003266.4) | Missense Mutation (SNP) | VAF 114/1088 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIM58 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.017); called by muse, mutect2
- ADGRE1 | c.2643C>T p.S881= | Silent (SNP) | VAF 31/239 reads (13%) | catalogued as rs745580800, COSV99166115; called by muse, mutect2, varscan2
- ASTN2 | c.2067G>A p.K689= (on ENST00000313400 / NM_001365069.1; = p.K638= on NM_014010.5) | Silent (SNP) | VAF 18/156 reads (12%) | called by muse, mutect2, varscan2
- CALR3 | c.723C>T p.S241= | Silent (SNP) | VAF 58/554 reads (10%) | catalogued as rs753171373, COSV99522002; called by muse, mutect2, varscan2
- COL23A1 | c.969C>T p.P323= | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as rs956291359, COSV101179609; called by muse, mutect2, varscan2
- DOP1B | c.4386G>A p.A1462= | Silent (SNP) | VAF 17/298 reads (6%) | catalogued as rs150837190; called by muse, mutect2
- HTR2C | c.1206C>T p.A402= | Silent (SNP) | VAF 45/371 reads (12%) | catalogued as COSV52208035; called by muse, mutect2, varscan2
- IKZF3 | c.1224G>A p.L408= | Silent (SNP) | VAF 50/516 reads (10%) | called by muse, mutect2
- NRXN3 | c.1383C>T p.S461= | Silent (SNP) | VAF 70/589 reads (12%) | catalogued as rs1048663441; called by muse, mutect2, varscan2
- NTRK2 | c.2202C>T p.S734= (on ENST00000323115 / NM_001369534.1; = p.S750= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 74/576 reads (13%) | catalogued as rs369724047, COSV99451817; called by muse, mutect2, varscan2
- PCDHGA7 | c.1947C>T p.H649= | Silent (SNP) | VAF 18/172 reads (10%) | catalogued as COSV54057740; called by muse, mutect2, varscan2
- RAB6D | c.612G>C p.G204= | Silent (SNP) | VAF 38/651 reads (6%) | called by muse, mutect2
- REN | c.321G>A p.S107= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs371626384; called by muse, mutect2, varscan2
- TMEM214 | c.1206C>T p.V402= | Silent (SNP) | VAF 25/211 reads (12%) | called by muse, mutect2, varscan2
- ZNF227 | c.1011G>A p.T337= | Silent (SNP) | VAF 23/161 reads (14%) | catalogued as rs768164418; called by muse, mutect2, varscan2
- A1BG | c.34+33G>A | Intron (SNP) | VAF 10/104 reads (10%) | catalogued as rs747919949, COSV99568352; called by muse, mutect2, varscan2
- ALDH1A2 | c.117+25G>A | Intron (SNP) | VAF 14/370 reads (4%) | called by muse, mutect2
- GRAMD2A | c.134+348G>A | Intron (SNP) | VAF 48/267 reads (18%) | catalogued as rs903824676; called by muse, mutect2, varscan2
